Somatic mutation profile of tumor specimen MP2PRT-PAVMJA-TMP1-A (aliquot MP2PRT-PAVMJA-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVMJA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 4.0 years (1,463 days).
Specimen MP2PRT-PAVMJA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 967bfe79-5ba6-42cf-b55d-460795e2f9db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVMJA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVMJA-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1179a99b-7180-4606-9932-52029ac01a87

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 6, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C4orf54 | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 90/1080 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1317857510; called by muse, mutect2
- HYDIN | c.7603C>T p.R2535C | Missense Mutation (SNP) | VAF 288/642 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1398603900, COSV59273352; called by muse, varscan2
- PTPN11 | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 96/321 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); catalogued as COSV61007145; called by muse, mutect2, varscan2
- SH3RF2 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 52/623 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as rs775124789, COSV63038309; called by muse, mutect2
- SLC27A6 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 142/606 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as rs776592048; called by muse, varscan2
- STAC | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 88/328 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs541117587; called by muse, mutect2, varscan2
- TRRAP | c.11164G>T p.D3722Y (on ENST00000359863 / NM_001244580.1; = p.D3693Y on NM_003496.3) | Missense Mutation (SNP) | VAF 147/527 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100705490; called by muse, mutect2, varscan2
- HDAC5 | c.299_300insC p.K100Nfs*4 | Frame Shift Ins (INS) | VAF 112/618 reads (18%) | called by mutect2, pindel*, varscan2
- VASH1 | c.300C>A p.D100E | Missense Mutation (SNP) | VAF 128/572 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FMN2 | c.3738C>T p.L1246= | Silent (SNP) | VAF 47/598 reads (8%) | catalogued as COSV60439114; called by muse, mutect2
- FOXI3 | c.168C>A p.L56= | Silent (SNP) | VAF 15/209 reads (7%) | called by muse, mutect2
- LRRC4B | c.1338C>T p.T446= | Silent (SNP) | VAF 180/600 reads (30%) | catalogued as rs936580936; called by muse, mutect2, varscan2
- PCDHA2 | c.1683C>T p.N561= | Silent (SNP) | VAF 79/974 reads (8%) | catalogued as COSV65371257; called by muse, mutect2
- RELN | c.6759C>T p.N2253= | Silent (SNP) | VAF 56/469 reads (12%) | catalogued as rs548135273, COSV59008995; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMTC2 | c.867C>G p.T289= | Silent (SNP) | VAF 106/357 reads (30%) | called by muse, mutect2, varscan2
- TRIM42 | c.-1C>A | 5'UTR (SNP) | VAF 61/235 reads (26%) | called by muse, mutect2, varscan2
